Somatic mutation profile of tumor specimen TCGA-43-A56V-01A (aliquot TCGA-43-A56V-01A-11D-A26M-08) from TCGA case TCGA-43-A56V, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.5 years (22,475 days).
Specimen TCGA-43-A56V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 564625f6-744a-4396-9543-c990a65658d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-A56V-10A (Blood Derived Normal), aliquot TCGA-43-A56V-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81e10aac-942a-4721-a479-ed2ecfba4cf0

The open-access MAF lists 238 somatic variants for this specimen: 167 protein-altering or splice-affecting, 68 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 68, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 2, 3'Flank 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.3079G>T p.E1027* | Nonsense Mutation (SNP) | VAF 13/18 reads (72%) | catalogued as rs1569153948, COSV100653229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | hotspot (GDC flag); catalogued as CS167193, COSV52662718, COSV52757202, COSV53162510; called by muse, mutect2, varscan2
- ACOT11 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100156874; called by muse, mutect2, varscan2
- ACSS3 | c.1577T>G p.L526* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV104370531, COSV99698681; called by muse, mutect2
- ADAMTSL4 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV99647202; called by muse, mutect2, varscan2
- ADCK1 | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV53078771, COSV99451589; called by muse, mutect2, varscan2
- ADCY8 | c.3527C>A p.P1176H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV53902311, COSV53931446; called by muse, mutect2
- AKAP9 | c.11133A>C p.Q3711H (on ENST00000359028; = p.Q3687H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as rs1283297655, COSV62343806; called by muse, mutect2, varscan2
- AMER1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100365962, COSV57671458; called by muse, mutect2, varscan2
- ANKRD13B | c.558G>T p.R186S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV101198894; called by muse, mutect2, varscan2
- ARHGAP12 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100260567; called by muse, mutect2, varscan2
- ASAP3 | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100369398; called by muse, mutect2
- ATP1A4 | c.980A>C p.E327A | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100927526; called by muse, mutect2, varscan2
- B3GLCT | c.1420T>G p.Y474D | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100587267; called by muse, mutect2, varscan2
- BBS12 | c.608A>T p.Q203L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.462); catalogued as COSV100044919; called by muse, mutect2, varscan2
- BOC | c.1646T>C p.M549T | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1207297374, COSV99848605; called by muse, mutect2, varscan2
- C2orf16 | c.1466C>G p.A489G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV100820770; called by muse, mutect2, varscan2
- CACNA2D4 | c.1579C>A p.L527I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54945614; called by muse, mutect2
- CCDC150 | c.301G>C p.V101L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99776854; called by muse, mutect2, varscan2
- CCN5 | c.405C>A p.S135R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV99509293, COSV99509530; called by muse, mutect2, varscan2
- CCSER1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100390706, COSV61437396; called by muse, mutect2, varscan2
- CD1A | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99192328; called by muse, mutect2, varscan2
- CDK14 | c.894A>C p.R298S (on ENST00000380050 / NM_001287135.2; = p.R280S on NM_012395.3) | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99724994; called by muse, mutect2
- CEP85L | c.1209G>T p.M403I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100821192; called by muse, mutect2, varscan2
- CHD8 | c.1515G>T p.K505N (on ENST00000646647 / NM_001170629.2; = p.K226N on NM_020920.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.655); catalogued as COSV101303139; called by muse, mutect2, varscan2
- CHST8 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99381030; called by muse, mutect2, varscan2
- CIT | c.4510A>G p.I1504V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99949407; called by muse, mutect2, varscan2
- COL15A1 | c.1205C>A p.P402Q | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.094); catalogued as COSV100897613; called by muse, mutect2, varscan2
- COL6A3 | c.8608C>T p.P2870S | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV99797908; called by muse, mutect2, varscan2
- COL9A1 | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs745369282, COSV57878243, COSV57881698; called by muse, mutect2, varscan2
- COMMD10 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV99174539; called by muse, mutect2, varscan2
- COPS7A | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99976441; called by muse, mutect2
- CPT2 | c.1860G>C p.W620C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV99598126; called by muse, mutect2, varscan2
- CSMD2 | c.1757C>A p.S586Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99589392; called by muse, mutect2, varscan2
- CSMD3 | c.5246C>A p.P1749H (on ENST00000297405 / NM_001363185.1; = p.P1645H on NM_052900.3) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99832794; called by muse, mutect2
- CTNNA2 | c.1384-1G>T p.X462_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100560326; called by muse, mutect2, varscan2
- CUBN | c.9208G>T p.V3070F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100912272; called by muse, mutect2, varscan2
- CYB5R4 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100859648; called by muse, mutect2, varscan2
- DAAM2 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99225518; called by muse, mutect2, varscan2
- DAB2 | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100297960; called by muse, mutect2, varscan2
- DCAF10 | c.942G>C p.L314F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99647667; called by muse, mutect2, varscan2
- DDX1 | c.2044G>T p.D682Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV99246214; called by muse, mutect2, varscan2
- DLK1 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.643); catalogued as COSV100375192; called by muse, mutect2, varscan2
- DNAH10 | c.1894G>T p.A632S (on ENST00000409039; = p.A571S on NM_207437.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV101292199; called by muse, mutect2
- DNAH3 | c.5607C>A p.D1869E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99767018; called by muse, mutect2, varscan2
- DNAH5 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99449091; called by muse, mutect2, varscan2
- DOCK10 | c.5971G>T p.G1991C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51346695; called by muse, mutect2
- DPEP1 | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV99878464; called by muse, mutect2, varscan2
- DUOX1 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.943); catalogued as COSV100367925; called by muse, mutect2, varscan2
- DYNC1H1 | c.5309G>A p.G1770D | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100794808; called by muse, mutect2
- EMC9 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as COSV99246194; called by muse, mutect2, varscan2
- EPHA4 | c.1916G>C p.R639P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99916352; called by muse, varscan2
- ERBB3 | c.2152G>T p.G718C | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99916697; called by muse, mutect2, varscan2
- FAM135B | c.1659C>A p.Y553* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99423183; called by muse, mutect2
- FAM71A | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99674559; called by muse, mutect2, varscan2
- FCHSD2 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100238270; called by muse, mutect2
- FKBP15 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV99438719; called by mutect2, varscan2
- FKBP5 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV100616153; called by muse, mutect2
- FKBP5 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100616154; called by muse, mutect2
- FMN2 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs371967368, COSV60425593; called by muse, mutect2, varscan2
- FMN2 | c.3776T>G p.V1259G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV100144765; called by muse, mutect2, varscan2
- FOXP1 | c.1703C>G p.P568R | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV100561548; called by muse, mutect2, varscan2
- FRMPD1 | c.2784G>A p.M928I | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100899546; called by muse, mutect2, varscan2
- FRY | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV100969163; called by muse, mutect2, varscan2
- FYN | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99991637, COSV99992703; called by muse, mutect2, varscan2
- GATAD2B | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100897853; called by muse, mutect2, varscan2
- GBP4 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100864373; called by muse, mutect2, varscan2
- GRIN2A | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100409557; called by muse, mutect2, varscan2
- GRIN2B | c.4353G>T p.Q1451H | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781050985, COSV101663014; called by muse, mutect2, varscan2
- HBE1 | c.51C>A p.S17R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1339205846, COSV99496191; called by muse, mutect2, varscan2
- HECTD1 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV101237362; called by muse, mutect2, varscan2
- HECW2 | c.2333C>A p.T778N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.07); catalogued as COSV99646958; called by muse, mutect2, varscan2
- HTR5A | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99839654; called by muse, varscan2
- IGF2BP2 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100649060; called by muse, mutect2, varscan2
- IMPG1 | c.671G>T p.R224I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs755198971, COSV100886337, COSV64055776; called by muse, mutect2, varscan2
- IQSEC3 | c.1094C>A p.A365E (on ENST00000538872 / NM_001170738.2; = p.A62E on NM_015232.1) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.089); catalogued as rs149068530, COSV58292209; called by muse, mutect2, varscan2
- IRS4 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100929535; called by muse, mutect2, varscan2
- JAM3 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100138117; called by muse, mutect2, varscan2
- KARS1 | c.749T>A p.I250N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100094001; called by muse, mutect2, varscan2
- KCNA5 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99363851; called by muse, mutect2, varscan2
- LAIR2 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.257); catalogued as COSV100003258; called by muse, mutect2, varscan2
- LAMA4 | c.922C>T p.H308Y (on ENST00000230538 / NM_001105206.3; = p.H301Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.655); catalogued as rs75775440; called by muse, mutect2, varscan2
- LGR4 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.783); catalogued as COSV100156547; called by muse, mutect2, varscan2
- LINGO1 | c.1478G>A p.G493D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62436431; called by muse, mutect2, varscan2
- LRRC4B | c.2026A>C p.S676R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV100975898; called by muse, mutect2, varscan2
- MFAP3L | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV100852668; called by muse, mutect2, varscan2
- MSH4 | c.1136A>C p.E379A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV99591490; called by muse, mutect2, varscan2
- MTERF1 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100699567; called by muse, mutect2, varscan2
- MUC17 | c.8143A>G p.T2715A | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.286); catalogued as COSV100072960; called by muse, varscan2
- NCKAP5 | c.1307T>A p.I436K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100491641; called by mutect2, varscan2
- NDUFAF5 | c.515A>T p.E172V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV100962103; called by muse, mutect2, varscan2
- NLRP13 | c.2938C>A p.R980S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs565649099, COSV100738195, COSV61620577; called by muse, mutect2, varscan2
- NOD2 | c.2792G>T p.W931L | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV100318498; called by muse, mutect2, varscan2
- NPEPL1 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100622413; called by muse, mutect2, varscan2
- NRXN1 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100454766; called by muse, mutect2, varscan2
- NRXN1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV101277535; called by muse, mutect2, varscan2
- NT5DC3 | c.1112A>T p.Y371F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV101230939; called by muse, mutect2, varscan2
- NTRK3 | c.2401G>A p.D801N (on ENST00000360948 / NM_001012338.2; = p.D787N on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.534); catalogued as rs199690201, COSV100712694, COSV100712785; called by muse, mutect2, varscan2
- NYX | c.1051A>T p.M351L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV100699402; called by muse, mutect2, varscan2
- OLR1 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100376361; called by muse, mutect2, varscan2
- OR1S1 | c.392T>A p.M131K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100515366; called by muse, mutect2, varscan2
- OR2T6 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100861546, COSV63217174; called by muse, mutect2, varscan2
- OR4A16 | c.238A>T p.M80L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100125184; called by muse, mutect2, varscan2
- OR4A16 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs145913777, COSV100125186; called by muse, mutect2, varscan2
- OR4C15 | c.350G>T p.G117V (on ENST00000314644; = p.G63V on NM_001001920.2) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs760399870, COSV100115628; called by muse, mutect2, varscan2
- OR4E2 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100330074; called by muse, mutect2, varscan2
- OR4K2 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as rs1566484754, COSV100064406; called by muse, mutect2, varscan2
- OR51A2 | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100985051; called by muse, mutect2, varscan2
- OR52B6 | c.564C>A p.C188* | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | catalogued as COSV100798485; called by muse, mutect2, varscan2
- OR5D14 | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100162322; called by muse, mutect2, varscan2
- OR5T3 | c.140A>T p.Y47F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100282778; called by muse, mutect2, varscan2
- OTOF | c.5582C>A p.A1861D (on ENST00000272371 / NM_194248.3; = p.A1094D on NM_004802.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV99717475; called by muse, mutect2, varscan2
- PALB2 | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV99848458; called by muse, mutect2, varscan2
- PAPPA2 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); catalogued as COSV100866762; called by muse, mutect2, varscan2
- PCDHA5 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as COSV100972248, COSV65355295; called by muse, mutect2, varscan2
- PCGF6 | c.558-2A>T p.X186_splice | Splice Site (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100461942; called by muse, mutect2, varscan2
- PDE11A | c.470T>A p.L157H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99612007; called by muse, mutect2, varscan2
- PDYN | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99452548, COSV99452966; called by muse, mutect2, varscan2
- PER2 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV54524967; called by muse, mutect2
- PGK2 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59163629; called by muse, mutect2, varscan2
- PIP4K2A | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100927377; called by muse, mutect2, varscan2
- PLOD2 | c.615G>C p.R205S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370572130; called by muse, mutect2, varscan2
- PPP2R3A | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as COSV53866406, COSV99386989; called by muse, mutect2, varscan2
- PRKAG3 | c.433T>A p.W145R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV99291913; called by muse, mutect2, varscan2
- PRKCE | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100077733; called by muse, mutect2
- PSPC1 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58889178; called by muse, mutect2, varscan2
- RAB36 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.184); catalogued as COSV99572196; called by muse, mutect2, varscan2
- RASAL3 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100640291; called by muse, mutect2, varscan2
- RELN | c.8156T>C p.V2719A | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV100633508; called by muse, mutect2
- RIMS1 | c.4178G>T p.R1393I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99326259; called by muse, mutect2
- RUFY4 | c.962T>A p.L321Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.364); catalogued as COSV100723043; called by muse, mutect2, varscan2
- RYR2 | c.8954C>A p.A2985E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100769819; called by muse, varscan2
- SCEL | c.1982A>G p.Q661R (on ENST00000349847 / NM_144777.3; = p.Q641R on NM_003843.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100582870; called by muse, mutect2, varscan2
- SEC11A | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99190007; called by muse, mutect2, varscan2
- SEMA3C | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV99542890; called by muse, mutect2, varscan2
- SERPINA3 | c.969C>G p.N323K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV101261679; called by muse, mutect2, varscan2
- SLC7A10 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV99472232; called by muse, mutect2, varscan2
- SMURF1 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100705411; called by muse, mutect2, varscan2
- SRRM1 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV100104544; called by muse, mutect2, varscan2
- ST8SIA1 | c.125G>T p.W42L | Missense Mutation (SNP) | VAF 177/292 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV99683071; called by muse, mutect2, varscan2
- STAT4 | c.1978T>C p.Y660H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100636056; called by muse, mutect2, varscan2
- SYNE1 | c.3783G>T p.K1261N (on ENST00000367255 / NM_182961.4; = p.K1268N on NM_033071.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV99562163; called by muse, mutect2, varscan2
- TAF7L | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100229463, COSV61256575; called by muse, mutect2, varscan2
- TAOK2 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664465; called by muse, mutect2, varscan2
- TECRL | c.697T>A p.Y233N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101168852; called by muse, mutect2, varscan2
- TENM3 | c.4663G>T p.A1555S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.31); catalogued as COSV101305080; called by muse, mutect2, varscan2
- TTC30A | c.502G>T p.G168* | Nonsense Mutation (SNP) | VAF 29/134 reads (22%) | catalogued as COSV100826175; called by muse, mutect2, varscan2
- TTLL8 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56722051, COSV99838287; called by muse, mutect2, varscan2
- UMOD | c.1909C>G p.L637V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.211); catalogued as COSV100208310; called by muse, mutect2, varscan2
- UMOD | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100208313; called by muse, mutect2, varscan2
- USH2A | c.10327A>T p.M3443L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100233667; called by muse, mutect2, varscan2
- VGF | c.1644C>A p.N548K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV99972997; called by muse, mutect2, varscan2
- WDR19 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56468026, COSV99975417; called by muse, mutect2, varscan2
- WDR59 | c.1880G>C p.W627S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV100049256; called by muse, mutect2, varscan2
- ZC3H15 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV100552057; called by muse, mutect2, varscan2
- ZNF449 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV100202958; called by muse, mutect2
- ZNF668 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs894416943, COSV100336633; called by muse, mutect2, varscan2
- ZNF831 | c.2555C>A p.S852Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV100925984, COSV64039613; called by muse, mutect2, varscan2
- AASS | c.2499dup p.D834Rfs*21 | Frame Shift Ins (INS) | VAF 50/184 reads (27%) | called by mutect2, pindel, varscan2
- BBS10 | c.787del p.T263Pfs*15 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- MME | c.1863_1869del p.M622Ifs*57 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- OR2M5 | c.298_299del p.Q100Nfs*21 | Frame Shift Del (DEL) | VAF 52/269 reads (19%) | called by pindel, varscan2
- OVCH1 | c.1724dup p.A576Rfs*47 | Frame Shift Ins (INS) | VAF 33/75 reads (44%) | called by mutect2, pindel, varscan2
- RPTN | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 105/371 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPANXB1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPATA31A1 | c.1095T>A p.N365K | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TPTE | c.1414C>A p.L472M (on ENST00000618007 / NM_199261.4; = p.L454M on NM_199259.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ADCYAP1 | c.324C>G p.L108= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs148570945, COSV99327506; called by muse, mutect2, varscan2
- ADGRL3 | c.2745T>C p.T915= (on ENST00000506720 / NM_001322402.2; = p.T847= on NM_015236.6) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101547064; called by muse, mutect2, varscan2
- ANK2 | c.9558G>T p.V3186= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100001304; called by muse, mutect2, varscan2
- AOPEP | c.744C>T p.Y248= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1227596131, COSV99468249; called by muse, mutect2, varscan2
- ATN1 | c.1494G>A p.Q498= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as rs199988271, COSV63110211; called by muse, varscan2
- BAZ1B | c.1749A>G p.Q583= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV100289713; called by muse, mutect2, varscan2
- CALHM5 | c.724C>T p.L242= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs374551311, COSV100635588; called by muse, mutect2, varscan2
- CDH8 | c.1170C>A p.V390= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100181193; called by muse, mutect2, varscan2
- CLCA1 | c.79C>T p.L27= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99322279; called by muse, mutect2, varscan2
- CLCN1 | c.2694G>A p.G898= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100577995; called by muse, mutect2, varscan2
- COL5A3 | c.282C>A p.I94= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV99318766; called by muse, mutect2, varscan2
- CPS1 | c.4449G>T p.V1483= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as COSV99242854; called by muse, mutect2, varscan2
- CRMP1 | c.1023G>A p.K341= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100271784; called by muse, mutect2, varscan2
- DNAI2 | c.792C>T p.D264= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as rs369894686; called by muse, mutect2, varscan2
- DNAI2 | c.1623G>T p.L541= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV100209742; called by muse, mutect2, varscan2
- EML1 | c.966T>G p.G322= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99214925; called by muse, mutect2, varscan2
- FAAH | c.1215C>G p.V405= | Silent (SNP) | VAF 23/244 reads (9%) | catalogued as COSV54544112; called by muse, mutect2
- GIMAP4 | c.435T>A p.A145= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99750640; called by muse, mutect2, varscan2
- GPA33 | c.360G>C p.S120= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100901018, COSV63300689; called by muse, mutect2, varscan2
- GPIHBP1 | c.472C>A p.R158= | Silent (SNP) | VAF 47/87 reads (54%) | catalogued as COSV100427359, COSV58209284; called by muse, mutect2, varscan2
- GPR139 | c.897G>T p.T299= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV100429827, COSV58503668; called by muse, mutect2, varscan2
- GRIN2A | c.3462C>A p.P1154= | Silent (SNP) | VAF 53/196 reads (27%) | catalogued as COSV100409556; called by muse, mutect2, varscan2
- GRIN2A | c.63G>T p.P21= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100409559; called by muse, mutect2, varscan2
- H2BC6 | c.213C>T p.F71= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as rs965410502, COSV100534411; called by muse, mutect2, varscan2
- HECW1 | c.3957A>C p.A1319= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV101223418; called by muse, mutect2, varscan2
- HIPK1 | c.837A>G p.L279= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1292925034, COSV101060339; called by muse, mutect2, varscan2
- ISG20L2 | c.975G>T p.V325= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV100494002; called by muse, mutect2, varscan2
- ITIH6 | c.417C>A p.G139= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV99513235, COSV99513988; called by muse, mutect2, varscan2
- KAZN | c.105G>A p.R35= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs368846918; called by muse, mutect2, varscan2
- KIT | c.606G>T p.L202= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV99854104; called by muse, mutect2, varscan2
- KLHL1 | c.429G>T p.L143= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100917177; called by muse, mutect2, varscan2
- LAMB4 | c.3780A>G p.E1260= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs1297757989, COSV99223804; called by muse, mutect2, varscan2
- LCT | c.3363G>A p.S1121= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs748568703, COSV99929348; called by muse, mutect2, varscan2
- LILRB5 | c.813C>A p.P271= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs1367942602, COSV100300323; called by muse, mutect2, varscan2
- LRRC7 | c.1656C>T p.I552= (on ENST00000651989 / NM_001370785.2; = p.I519= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1298215012, COSV99226367; called by muse, mutect2
- LRRIQ4 | c.510C>A p.I170= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as COSV100540222; called by muse, mutect2, varscan2
- MCTP1 | c.183G>T p.P61= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV101542414; called by muse, mutect2, varscan2
- MUC5B | c.12687C>A p.P4229= | Silent (SNP) | VAF 46/213 reads (22%) | catalogued as COSV101500281; called by muse, mutect2, varscan2
- MYH4 | c.3600C>T p.H1200= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99701114, COSV99701369; called by muse, mutect2, varscan2
- MYO5A | c.2952G>T p.R984= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100697600; called by muse, mutect2, varscan2
- NID2 | c.3153C>A p.P1051= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV99356420; called by muse, mutect2, varscan2
- NLRC4 | c.2178A>T p.I726= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100707348; called by muse, mutect2, varscan2
- NYX | c.918G>T p.A306= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs965071108, COSV100699401; called by muse, mutect2, varscan2
- OPRPN | c.222T>C p.S74= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as COSV101271086; called by muse, mutect2, varscan2
- OR2AG1 | c.726T>C p.S242= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100264852; called by muse, mutect2, varscan2
- OR5AC2 | c.666T>C p.R222= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100684354; called by muse, mutect2, varscan2
- OR6K2 | c.246G>A p.L82= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100656774; called by muse, mutect2, varscan2
- PACSIN3 | c.531C>T p.D177= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1161143444, COSV100096319; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1173G>A p.T391= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs139912302; called by muse, varscan2
- PCLO | c.795T>G p.P265= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100431705; called by muse, mutect2, varscan2
- PDE1C | c.1524T>C p.A508= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs986518076, COSV100372341; called by muse, mutect2, varscan2
- PLA2G3 | c.24T>C p.F8= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs753520211, COSV99311609; called by muse, mutect2, varscan2
- PLEKHB1 | c.399T>A p.A133= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99909502; called by muse, varscan2
- POU3F4 | c.993A>G p.Q331= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100937214; called by muse, mutect2, varscan2
- RASGRP2 | c.603C>T p.N201= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs551642780, COSV100818239; called by muse, mutect2, varscan2
- RCOR1 | c.1314A>G p.Q438= | Silent (SNP) | VAF 82/222 reads (37%) | catalogued as COSV99217438; called by muse, mutect2, varscan2
- RSPH4A | c.663T>A p.T221= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99994104; called by muse, mutect2
- RTL1 | c.243C>A p.S81= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV101128255; called by muse, mutect2, varscan2
- SEC16A | c.3324G>A p.A1108= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1564525806, COSV99257712; called by muse, mutect2, varscan2
- SETDB2 | c.168G>C p.V56= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs1295689180, COSV99320720; called by muse, mutect2, varscan2
- SLC24A2 | c.1668C>A p.A556= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99646435; called by muse, mutect2, varscan2
- SLC27A6 | c.162G>A p.V54= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs1289147856, COSV99322620; called by muse, mutect2, varscan2
- SPACA1 | c.285T>A p.V95= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99389503; called by muse, mutect2
- SPATA31A1 | c.1470G>T p.R490= | Silent (SNP) | VAF 98/396 reads (25%) | called by muse, mutect2, varscan2
- TECRL | c.696C>A p.A232= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV101168853; called by muse, mutect2, varscan2
- UNC13A | c.1221G>T p.T407= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99408089; called by muse, varscan2
- WHAMM | c.1953A>T p.P651= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99724877, COSV99725146; called by muse, varscan2
- WSCD2 | c.1329C>A p.A443= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs776452023, COSV99774510; called by muse, mutect2, varscan2
- FRMPD2B | n.1189C>G | RNA (SNP) | VAF 19/56 reads (34%) | called by mutect2, varscan2
- MTRNR2L6 | chr7:142671089 C>A | 3'Flank (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- NKX6-3 | c.553-558C>A | Intron (SNP) | VAF 10/31 reads (32%) | catalogued as COSV101570818; called by muse, mutect2, varscan2
